Somatic mutation profile of tumor specimen TCGA-N5-A4RV-01A (aliquot TCGA-N5-A4RV-01A-21D-A28R-08) from TCGA case TCGA-N5-A4RV, project TCGA-UCS (Uterine Carcinosarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mullerian mixed tumor; Tissue or organ of origin: Uterus, NOS; FIGO stage: Stage IA; Age at diagnosis: 62.9 years (22,978 days).
Specimen TCGA-N5-A4RV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 75bac20c-7351-4cdc-a218-e495cec7f210.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-N5-A4RV-10A (Blood Derived Normal), aliquot TCGA-N5-A4RV-10A-01D-A28U-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a36137a1-e672-4422-84c1-193d26f0b48d

The open-access MAF lists 61 somatic variants for this specimen: 44 protein-altering or splice-affecting, 17 silent.
By variant classification: Missense Mutation 38, Silent 17, Nonsense Mutation 3, Frame Shift Del 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.428T>G p.V143G | Missense Mutation (SNP) | VAF 37/38 reads (97%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1555526241, CM1511132, COSV52737174, COSV52760297, COSV52868891; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANXA6 | c.692G>C p.R231P | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.83); catalogued as rs370325414, COSV100637121; called by muse, mutect2, varscan2
- CAPN3 | c.1465C>G p.R489G | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM980303, COSV100520606; called by muse, mutect2, varscan2
- CCDC88B | c.1334C>T p.A445V | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs756871869, COSV57266726; called by muse, mutect2, varscan2
- DIRAS2 | c.271C>T p.R91* | Nonsense Mutation (SNP) | VAF 89/94 reads (95%) | catalogued as COSV65370662; called by muse, mutect2, varscan2
- FZD2 | c.1688C>T p.T563I | Missense Mutation (SNP) | VAF 19/32 reads (59%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.889); catalogued as rs1213204785, COSV104408881; called by muse, mutect2
- GRIA3 | c.361C>A p.H121N | Missense Mutation (SNP) | VAF 30/120 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); catalogued as COSV52053348; called by muse, mutect2, varscan2
- IL6ST | c.196G>A p.V66I | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1036903182; called by muse, mutect2, varscan2
- KIAA0895L | c.236G>A p.R79H | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs755161509; called by muse, mutect2, varscan2
- RB1 | c.2063T>G p.L688R | Missense Mutation (SNP) | VAF 34/35 reads (97%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM074471, COSV57306650; called by muse, mutect2, varscan2
- ZNF676 | c.1096G>C p.E366Q (on ENST00000650058; = p.E334Q on NM_001001411.3) | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV68092648; called by muse, varscan2
- ZZZ3 | c.2090G>T p.S697I | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100890425; called by muse, mutect2, varscan2
- AC024940.1 | n.341G>T | Splice Region (SNP) | VAF 5/21 reads (24%) | called by muse, varscan2
- ALG12 | c.1385T>G p.L462R | Missense Mutation (SNP) | VAF 12/62 reads (19%) | PolyPhen possibly damaging (0.59); called by muse, mutect2, varscan2
- ATG9B | c.1868G>A p.R623Q | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- BCL2L13 | c.545G>C p.G182A | Missense Mutation (SNP) | VAF 37/87 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C1orf74 | c.315G>C p.E105D | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- CATSPER1 | c.2240C>A p.A747E | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- CHD4 | c.3110G>A p.G1037E (on ENST00000357008 / NM_001363606.2; = p.G1050E on NM_001273.5) | Missense Mutation (SNP) | VAF 64/67 reads (96%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CHD6 | c.2088_2089del p.E696Dfs*4 | Frame Shift Del (DEL) | VAF 57/144 reads (40%) | called by pindel, varscan2
- DPP4 | c.1970_1979del p.S657Cfs*30 | Frame Shift Del (DEL) | VAF 29/53 reads (55%) | called by mutect2, pindel, varscan2
- F2RL1 | c.82G>T p.G28* | Nonsense Mutation (SNP) | VAF 5/13 reads (38%) | called by muse, mutect2, varscan2
- FRMPD3 | c.723C>A p.D241E | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.8); PolyPhen benign (0.321); called by muse, mutect2, varscan2
- IGF2R | c.6673G>C p.V2225L | Missense Mutation (SNP) | VAF 20/236 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.308); called by muse, mutect2
- KIF1A | c.1004A>T p.D335V | Missense Mutation (SNP) | VAF 29/38 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KMT2D | c.16563C>G p.H5521Q | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- LRP1B | c.11828C>T p.P3943L | Missense Mutation (SNP) | VAF 30/46 reads (65%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MX2 | c.1633C>G p.L545V | Missense Mutation (SNP) | VAF 34/62 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MXD1 | c.581G>C p.S194T | Missense Mutation (SNP) | VAF 36/117 reads (31%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- NOTCH1 | c.4035T>A p.C1345* | Nonsense Mutation (SNP) | VAF 12/14 reads (86%) | called by muse, mutect2, varscan2
- PDZD3 | c.430G>A p.V144M (on ENST00000531114; = p.V78M on NM_024791.4) | Missense Mutation (SNP) | VAF 45/46 reads (98%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PLPPR4 | c.575T>A p.I192N | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- PRDM1 | c.779C>A p.P260H | Missense Mutation (SNP) | VAF 207/437 reads (47%) | SIFT tolerated (0.21); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SCD | c.296A>T p.Y99F | Missense Mutation (SNP) | VAF 102/174 reads (59%) | SIFT tolerated (0.34); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SETDB1 | c.1577A>G p.Y526C | Missense Mutation (SNP) | VAF 28/121 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.237); called by muse, mutect2, varscan2
- SI | c.5131A>C p.I1711L | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- SLITRK3 | c.322C>A p.L108I | Missense Mutation (SNP) | VAF 24/34 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- STX7 | c.365T>G p.V122G | Missense Mutation (SNP) | VAF 40/96 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.692); called by muse, mutect2, varscan2
- SUPT20HL2 | c.295T>A p.F99I | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT tolerated (0.39); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- TREML2 | c.683T>G p.I228S | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT tolerated (0.13); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TSPOAP1 | c.3940G>A p.E1314K | Missense Mutation (SNP) | VAF 46/99 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- UACA | c.3865C>G p.Q1289E | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.554); called by muse, mutect2, varscan2
- USP10 | c.1205A>G p.N402S | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- USP51 | c.40G>A p.G14R | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- ACACB | c.6378A>G p.G2126= | Silent (SNP) | VAF 45/237 reads (19%) | called by muse, mutect2, varscan2
- C5orf51 | c.6G>C p.A2= | Silent (SNP) | VAF 15/39 reads (38%) | called by muse, mutect2, varscan2
- C8orf76 | c.240C>A p.I80= | Silent (SNP) | VAF 36/84 reads (43%) | called by muse, mutect2, varscan2
- CNTNAP4 | c.2544A>T p.T848= | Silent (SNP) | VAF 49/156 reads (31%) | catalogued as COSV100273578; called by muse, mutect2, varscan2
- COL20A1 | c.3009C>T p.P1003= | Silent (SNP) | VAF 10/14 reads (71%) | catalogued as rs771914301, COSV58911381; called by muse, varscan2
- CSMD3 | c.6360T>G p.G2120= (on ENST00000297405 / NM_001363185.1; = p.G2016= on NM_052900.3) | Silent (SNP) | VAF 70/119 reads (59%) | called by muse, mutect2, varscan2
- DNAH17 | c.6237C>T p.D2079= | Silent (SNP) | VAF 33/170 reads (19%) | catalogued as rs747921690; called by muse, mutect2, varscan2
- DYNC2H1 | c.11589T>C p.A3863= | Silent (SNP) | VAF 46/50 reads (92%) | catalogued as rs1343580091; called by muse, mutect2, varscan2
- EHMT2 | c.3465C>T p.G1155= | Silent (SNP) | VAF 4/48 reads (8%) | catalogued as rs1198468057; called by muse, mutect2
- FFAR2 | c.939C>T p.D313= | Silent (SNP) | VAF 18/78 reads (23%) | catalogued as rs201365846; called by muse, mutect2, varscan2
- MELTF | c.1431C>T p.H477= | Silent (SNP) | VAF 55/87 reads (63%) | catalogued as rs745379113, COSV56384766, COSV99586597; called by muse, mutect2, varscan2
- MYRIP | c.1413A>G p.R471= | Silent (SNP) | VAF 32/95 reads (34%) | called by muse, mutect2, varscan2
- OR2A12 | c.522C>T p.N174= | Silent (SNP) | VAF 33/104 reads (32%) | catalogued as rs771253895; called by muse, mutect2, varscan2
- SLC25A39 | c.654C>T p.G218= (on ENST00000377095 / NM_001143780.3; = p.G210= on NM_016016.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 11/48 reads (23%) | called by muse, mutect2, varscan2
- SLCO2A1 | c.1335C>A p.R445= | Silent (SNP) | VAF 61/378 reads (16%) | called by muse, mutect2, varscan2
- TMEM144 | c.375G>A p.P125= | Silent (SNP) | VAF 33/115 reads (29%) | catalogued as rs780150839; called by muse, mutect2, varscan2
- USP26 | c.429T>A p.S143= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as COSV63709823; called by muse, mutect2, varscan2
